Somatic mutation profile of tumor specimen TCGA-BR-4369-01A (aliquot TCGA-BR-4369-01A-01D-1158-08) from TCGA case TCGA-BR-4369, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 75.3 years (27,509 days).
Specimen TCGA-BR-4369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f211f81a-f052-4456-bb1a-460219b7b810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4369-11A (Solid Tissue Normal), aliquot TCGA-BR-4369-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c2995f0-3bd9-4997-896d-8d4ba32a42ce

The open-access MAF lists 184 somatic variants for this specimen: 135 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 47, Nonsense Mutation 8, Frame Shift Del 2, Intron 2, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 23/200 reads (12%) | catalogued as rs587777497, CM145495, COSV52038469, COSV99812028; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13606T>G p.L4536V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68948859, COSV68951754; called by muse, mutect2, varscan2
- ACSM2B | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 139/408 reads (34%) | catalogued as COSV61658918, COSV61659271; called by muse, mutect2, varscan2
- ADAMTS16 | c.3155A>C p.K1052T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV56997924; called by muse, mutect2
- ADAMTS16 | c.3626A>G p.K1209R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs755448042, COSV56993229, COSV56997939; called by muse, mutect2, varscan2
- ADAT1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 134/758 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV57187532; called by muse, varscan2
- AHCYL2 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61489350; called by muse, mutect2, varscan2
- ANKRD13B | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as rs1250864843, COSV67474144; called by muse, varscan2
- AP4B1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528147130, COSV56725492; called by muse, mutect2, varscan2
- APC | c.5759G>A p.R1920Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs587780599, CD086483, COSV57336002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP31 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV51796113; called by muse, mutect2, varscan2
- ARID4A | c.3481C>G p.P1161A | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as rs1400796145, COSV62165151; called by muse, mutect2
- ATAD5 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766096038, COSV58976625; called by muse, mutect2, varscan2
- ATP1B4 | c.505G>A p.V169I (on ENST00000218008 / NM_001142447.3; = p.V165I on NM_012069.5) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as rs763182565, COSV54313957; called by muse, mutect2, varscan2
- BCL7B | c.267C>T p.D89= | Splice Region (SNP) | VAF 7/46 reads (15%) | catalogued as rs782570753, COSV56270981; called by muse, mutect2, varscan2
- BTAF1 | c.5246T>G p.V1749G | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56436497; called by muse, mutect2, varscan2
- CA10 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 86/897 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780948449, COSV53337468; called by muse, mutect2
- CADM3 | c.1063T>G p.L355V (on ENST00000368125 / NM_001127173.3; = p.L389V on NM_021189.5) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63676740; called by muse, mutect2, varscan2
- CCNT2 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV51474793; called by muse, mutect2, varscan2
- CD163L1 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.14); catalogued as COSV100549601, COSV58020248; called by muse, mutect2, varscan2
- CD1E | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63771967; called by muse, mutect2
- CENPF | c.2421G>T p.M807I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV65276677; called by muse, mutect2, varscan2
- CNGB3 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60693814; called by muse, mutect2, varscan2
- CNKSR2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as COSV54261336; called by muse, mutect2, varscan2
- COCH | c.784A>T p.I262F (on ENST00000216361 / NM_001347720.1; = p.I197F on NM_004086.3) | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53551850; called by muse, varscan2
- COL24A1 | c.2944A>C p.S982R | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV65309667; called by muse, mutect2, varscan2
- CORIN | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370951437, COSV56699708; called by muse, mutect2, varscan2
- CPNE4 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV70197108; called by muse, mutect2, varscan2
- CPS1 | c.3209A>G p.K1070R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV51817031; called by muse, mutect2, varscan2
- CSMD3 | c.1542A>C p.E514D (on ENST00000297405 / NM_001363185.1; = p.E410D on NM_052900.3) | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.926); catalogued as COSV52135560; called by muse, mutect2, varscan2
- CUBN | c.3586A>C p.K1196Q | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV64721360; called by muse, mutect2, varscan2
- CYP7B1 | c.228A>C p.Q76H | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59592840; called by muse, mutect2, varscan2
- DDI1 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV56385580; called by muse, mutect2, varscan2
- DDX42 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 84/446 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV63790692; called by muse, mutect2, varscan2
- DSP | c.5774A>G p.Q1925R | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV65794009; called by muse, mutect2, varscan2
- EHMT2 | c.2717A>T p.K906M | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV64997017; called by muse, mutect2, varscan2
- EPB41L3 | c.1382A>G p.Q461R | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV59460771; called by muse, mutect2, varscan2
- EPRS1 | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65100266; called by muse, mutect2, varscan2
- EVC2 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV60397820; called by muse, mutect2, varscan2
- FAM78A | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV55992773; called by muse, mutect2, varscan2
- FAT3 | c.12896G>A p.C4299Y | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV53142811; called by muse, mutect2, varscan2
- FCGBP | c.4738G>A p.V1580M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1221538968, COSV55444929; called by muse, mutect2
- FMNL1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58957215; called by muse, mutect2, varscan2
- FOXP2 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as COSV63489833; called by muse, mutect2, varscan2
- GAD1 | c.466T>G p.L156V | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV60153155, COSV60153288; called by muse, mutect2, varscan2
- GGN | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53057833; called by muse, mutect2, varscan2
- GPR143 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.068); catalogued as COSV66632785; called by muse, mutect2, varscan2
- GRIK1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.87); catalogued as rs975762689, COSV58717254; called by muse, mutect2
- GRXCR1 | c.5T>G p.L2R | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.206); catalogued as COSV67670168, COSV67674256; called by muse, mutect2, varscan2
- GSR | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs767042164, COSV55321859; called by muse, mutect2, varscan2
- H2BC8 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55126012, COSV55127353; called by muse, mutect2, varscan2
- HBG1 | c.316-2A>T p.X106_splice | Splice Site (SNP) | VAF 60/104 reads (58%) | catalogued as COSV100400561; called by muse, mutect2, varscan2
- HFM1 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.171); catalogued as COSV54032521; called by muse, mutect2, varscan2
- HTR1F | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV60390328; called by muse, mutect2, varscan2
- IGFBP3 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51872966; called by muse, mutect2
- INSYN2A | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs780028933, COSV54748852; called by muse, mutect2, varscan2
- KCNE2 | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV51710610; called by muse, mutect2, varscan2
- KCNMB2 | c.453T>G p.N151K | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV64201510; called by muse, mutect2, varscan2
- KCNV2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377667539, CM162525, COSV66056902; called by muse, mutect2, varscan2
- KIF16B | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761946914, COSV61709804; called by muse, mutect2
- KIF27 | c.1664T>G p.L555R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52825178; called by muse, mutect2, varscan2
- KLHDC8B | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | catalogued as COSV60411882; called by muse, mutect2, varscan2
- KLHL4 | c.1418T>G p.V473G | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64141890, COSV64145034; called by muse, mutect2, varscan2
- KMT2C | c.7747G>C p.E2583Q | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV51467960; called by muse, mutect2, varscan2
- KMT2E | c.4835C>T p.S1612F | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV57576607; called by muse, mutect2, varscan2
- LARP1 | c.2491C>T p.H831Y (on ENST00000518297 / NM_033551.3; = p.H754Y on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60429065; called by muse, mutect2, varscan2
- MAP3K21 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV64045562; called by muse, mutect2
- MMP16 | c.1294A>G p.S432G | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs1459050274, COSV54176408; called by muse, mutect2, varscan2
- MRTFA | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs138116355; called by muse, mutect2, varscan2
- MUC16 | c.7791G>T p.L2597F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67479457; called by muse, mutect2, varscan2
- MYH7B | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs754106966, COSV53422619; called by muse, varscan2
- MYH8 | c.3478A>T p.T1160S | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.654); catalogued as COSV67968838; called by muse, mutect2
- NCKAP5 | c.4405T>C p.S1469P | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV58459517; called by muse, mutect2, varscan2
- NDUFS1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51911505; called by muse, mutect2
- NEURL2 | c.597T>A p.D199E | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51943420; called by muse, mutect2, varscan2
- OR4C15 | c.1060A>C p.I354L (on ENST00000314644; = p.I300L on NM_001001920.2) | Missense Mutation (SNP) | VAF 135/202 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58954149; called by muse, mutect2, varscan2
- OR52N4 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 272/378 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57891796; called by muse, varscan2
- ORMDL1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57877232; called by muse, mutect2, varscan2
- OVCH2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs544648142, COSV71952967; called by muse, mutect2, varscan2
- OXNAD1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53267570; called by muse, mutect2, varscan2
- PAPOLG | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV53184051; called by muse, mutect2, varscan2
- PAQR5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | catalogued as COSV61817864; called by muse, mutect2
- PARP14 | c.173_175del p.F58del | In Frame Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs759585901; called by pindel, varscan2
- PCDHA3 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs781949159, COSV100793242, COSV63543094; called by muse, mutect2
- PCDHAC1 | c.1076T>A p.I359N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53859972; called by muse, mutect2, varscan2
- PCDHB2 | c.2300A>C p.K767T | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV99164157; called by muse, mutect2, varscan2
- PCDHGA1 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs1373664480, COSV65297881; called by muse, mutect2, varscan2
- PICK1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs945697657, COSV57636144; called by muse, mutect2, varscan2
- PIGC | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51130207; called by muse, mutect2, varscan2
- PIK3R1 | c.1714C>T p.Q572* (on ENST00000521381 / NM_181523.3; = p.Q302* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | catalogued as rs1390357148, COSV57132417; called by muse, mutect2, varscan2
- PRKRA | c.632T>A p.L211* | Nonsense Mutation (SNP) | VAF 65/246 reads (26%) | catalogued as COSV57869575; called by muse, mutect2, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2, varscan2
- PTH2R | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55913605; called by muse, mutect2, varscan2
- PTPN12 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50365016; called by muse, mutect2, varscan2
- PTPRD | c.4549A>C p.T1517P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61963390; called by muse, mutect2, varscan2
- RBBP4 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65132926; called by muse, mutect2, varscan2
- REG3G | c.421T>G p.L141V | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV55450555; called by muse, mutect2, varscan2
- RIMS2 | c.3977A>G p.K1326R | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1322791617, COSV51700678; called by muse, varscan2
- RIMS2 | c.4553T>A p.V1518D (on ENST00000666250 / NM_001348490.2; = p.V1089D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51700693; called by muse, mutect2, varscan2
- RLF | c.3159G>T p.R1053S | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV65652431; called by muse, mutect2
- RNF149 | c.1195A>T p.I399F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV54864774; called by muse, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2, varscan2
- SERAC1 | c.1179A>C p.K393N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV65597293; called by muse, mutect2
- SETBP1 | c.740G>C p.S247T | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.085); catalogued as COSV56329403; called by muse, mutect2, varscan2
- SH2B3 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333297458, COSV57984929; called by muse, mutect2, varscan2
- SLC6A6 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770780822, COSV62651087; called by muse, mutect2, varscan2
- SLC9A1 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV56055130; called by muse, mutect2
- SNTG2 | c.1114T>A p.L372M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); catalogued as COSV57984512, COSV57995286, COSV58009247; called by muse, mutect2, varscan2
- SPART | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1461195359, COSV62086879; called by muse, mutect2, varscan2
- SPEF2 | c.2633T>C p.L878P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV61550901; called by muse, mutect2, varscan2
- SPEG | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 129/433 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs375953839; called by muse, mutect2, varscan2
- SPHKAP | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60886953; called by muse, mutect2, varscan2
- SPTA1 | c.5207T>G p.V1736G | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63756613; called by muse, mutect2, varscan2
- SPTAN1 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 65/223 reads (29%) | catalogued as rs1484319243, COSV63988443; called by muse, mutect2, varscan2
- TCAIM | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV61241643; called by muse, mutect2, varscan2
- TDRD10 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV52726206; called by muse, mutect2, varscan2
- TEKT4 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs782046554, COSV54623213; called by muse, mutect2, varscan2
- TLR4 | c.1492T>G p.L498V (on ENST00000355622 / NM_138554.5; = p.L458V on NM_003266.4) | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2, varscan2
- TMEM196 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.584); catalogued as COSV68254528, COSV68255641; called by muse, mutect2
- TNFSF18 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 43/293 reads (15%) | catalogued as COSV53440874; called by muse, mutect2, varscan2
- TRBV5-1 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs867156097; called by muse, mutect2, varscan2
- TRH | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV57015367; called by muse, mutect2, varscan2
- TRIML1 | c.1217A>C p.K406T | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV60195587; called by muse, mutect2, varscan2
- TRMT10A | c.836T>G p.V279G | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV56745616; called by muse, mutect2, varscan2
- TRPS1 | c.2211A>C p.K737N (on ENST00000220888 / NM_001330599.2; = p.K750N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/564 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55251184; called by muse, mutect2, varscan2
- TRRAP | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV62840550, COSV62849348; called by muse, mutect2
- UNC5D | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747771719, COSV54813130; called by muse, mutect2, varscan2
- UPK1A | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV55878647; called by muse, mutect2, varscan2
- ZBED9 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs759584881, COSV101509099; called by muse, mutect2, varscan2
- ZNF461 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.161); catalogued as rs1210003556, COSV64453734, COSV64454333; called by muse, mutect2, varscan2
- ZNF670 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63608517; called by muse, mutect2, varscan2
- ZSCAN18 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs376941867, COSV99559091; called by muse, mutect2, varscan2
- ANKRD11 | c.7191_7210del p.Q2397Hfs*128 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel
- IGHV1OR15-9 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); called by muse, varscan2
- SPTA1 | c.6259del p.D2087Tfs*19 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1281T>C p.T427= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV51846496; called by muse, mutect2, varscan2
- ADGRB3 | c.4011T>C p.H1337= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as rs781151198, COSV53252753; called by muse, mutect2, varscan2
- AHCTF1 | c.2070T>C p.N690= (on ENST00000366508; = p.N664= on NM_015446.5) | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV58252579; called by muse, mutect2, varscan2
- CHL1 | c.1335C>T p.C445= (on ENST00000397491 / NM_001253387.1; = p.C461= on NM_006614.4) | Silent (SNP) | VAF 32/224 reads (14%) | catalogued as rs747335710, COSV56597177; called by muse, mutect2, varscan2
- CNGB3 | c.1248T>G p.T416= | Silent (SNP) | VAF 82/162 reads (51%) | catalogued as COSV60693805; called by muse, mutect2, varscan2
- COL6A1 | c.2247C>T p.I749= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV62614350; called by muse, mutect2
- DCLK1 | c.477T>G p.A159= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as COSV55197122, COSV99711315; called by muse, mutect2, varscan2
- DMD | c.3030G>A p.A1010= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs72468666, COSV63774019; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DNAI4 | c.630G>A p.L210= | Silent (SNP) | VAF 75/359 reads (21%) | catalogued as COSV64019224; called by muse, mutect2, varscan2
- EIF2AK3 | c.1161C>T p.Y387= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as COSV57549934; called by muse, mutect2, varscan2
- ESRRG | c.873G>A p.T291= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1318553756, COSV63170413; called by muse, mutect2, varscan2
- FAT4 | c.13248G>A p.L4416= | Silent (SNP) | VAF 35/316 reads (11%) | catalogued as COSV58697147; called by muse, mutect2, varscan2
- FOXO1 | c.1380A>G p.G460= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV65427597; called by muse, mutect2, varscan2
- GABRA1 | c.318A>C p.G106= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV50111176; called by muse, mutect2
- GFPT2 | c.1945C>T p.L649= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV53810449; called by muse, mutect2, varscan2
- GLP2R | c.444C>T p.N148= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs771274770, COSV52326182, COSV52327074; called by muse, mutect2, varscan2
- GNB3 | c.735G>A p.S245= | Silent (SNP) | VAF 64/240 reads (27%) | catalogued as rs112732503, COSV57529648; called by muse, mutect2, varscan2
- GPR139 | c.987G>A p.P329= | Silent (SNP) | VAF 82/343 reads (24%) | catalogued as rs1185530060, COSV58501525, COSV58503622, COSV58503739; called by muse, mutect2, varscan2
- GPR155 | c.912C>T p.G304= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs763666962, COSV55040363; called by muse, mutect2, varscan2
- GYS1 | c.609C>T p.T203= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as rs1277950492, COSV54404060; called by muse, mutect2, varscan2
- HCN1 | c.2361C>T p.S787= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs758609806, COSV57510971; called by muse, mutect2, varscan2
- HELZ2 | c.7782G>T p.V2594= (on ENST00000467148 / NM_001037335.2; = p.V2025= on NM_033405.3) | Silent (SNP) | VAF 37/301 reads (12%) | catalogued as COSV64443155; called by muse, mutect2, varscan2
- KCNA5 | c.1494G>A p.S498= | Silent (SNP) | VAF 71/306 reads (23%) | catalogued as rs576837393, COSV52905200; called by muse, mutect2, varscan2
- KCNN2 | c.927C>T p.C309= (on ENST00000264773; = p.C521= on NM_021614.4) | Silent (SNP) | VAF 40/285 reads (14%) | catalogued as COSV53293857; called by muse, mutect2, varscan2
- MMP2 | c.207G>C p.V69= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV54603286; called by muse, mutect2, varscan2
- MOS | c.375G>A p.T125= | Silent (SNP) | VAF 114/405 reads (28%) | catalogued as COSV61336086; called by muse, mutect2, varscan2
- NEXMIF | c.4443T>C p.S1481= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV50026823, COSV50056073; called by muse, mutect2, varscan2
- NXNL2 | c.171C>T p.A57= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV65474610; called by muse, mutect2, varscan2
- OR10Z1 | c.664T>C p.L222= | Silent (SNP) | VAF 62/415 reads (15%) | catalogued as COSV63524121, COSV63525670; called by muse, mutect2, varscan2
- OR2L3 | c.744T>C p.T248= | Silent (SNP) | VAF 34/468 reads (7%) | catalogued as COSV63455722, COSV63455810; called by muse, mutect2
- OR8H1 | c.784A>C p.R262= | Silent (SNP) | VAF 123/197 reads (62%) | catalogued as COSV57294909; called by muse, mutect2, varscan2
- PCDHB5 | c.1095C>T p.A365= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as COSV50658566; called by muse, mutect2
- PDE12 | c.549C>T p.L183= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as COSV100239679; called by muse, mutect2, varscan2
- PDHB | c.51G>A p.G17= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV57057288; called by muse, mutect2, varscan2
- PIK3R3 | c.69G>A p.S23= | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as COSV53109321; called by muse, varscan2
- PSMA8 | c.661A>C p.R221= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV57603767; called by muse, mutect2, varscan2
- PXDNL | c.2547C>T p.H849= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1309161953, COSV62493249; called by muse, mutect2, varscan2
- SCN3A | c.3279C>T p.F1093= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV51802267; called by muse, mutect2
- SLC6A14 | c.1599G>A p.T533= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs782476255, COSV64147802; called by muse, mutect2, varscan2
- SLFNL1 | c.618C>T p.I206= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs757413470, COSV57235039; called by muse, mutect2, varscan2
- SNX29 | c.2415C>T p.N805= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs572049168, COSV60064963; called by muse, mutect2, varscan2
- SRCIN1 | c.2745C>A p.A915= (on ENST00000621492; = p.A881= on NM_025248.3) | Silent (SNP) | VAF 9/245 reads (4%) | called by muse, mutect2
- TFAP2B | c.732G>A p.S244= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs778271758, COSV53829379; called by muse, mutect2, varscan2
- THSD7B | c.3462T>G p.T1154= (on ENST00000272643; = p.T1152= on NM_001316349.2) | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as COSV55711919; called by muse, mutect2
- TMEM131L | c.3321G>A p.L1107= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs1288468787, COSV53647414; called by muse, mutect2, varscan2
- WIPI2 | c.522G>A p.A174= | Silent (SNP) | VAF 20/235 reads (9%) | catalogued as rs149226373; called by muse, mutect2
- ZBED9 | c.291G>T p.L97= | Silent (SNP) | VAF 32/269 reads (12%) | catalogued as COSV101509101; called by muse, mutect2, varscan2
- DNAH1 | c.9364-92C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20166T>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as COSV67446885; called by muse, mutect2, varscan2
